Somatic mutation profile of tumor specimen 0DU1XC from CCDI case PBCKPY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Choroid plexus carcinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (808 days).
Specimen 0DU1XC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3f7d69d-9171-4374-be24-a65cbf360746.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU1WB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0391c1e2-0283-4177-bdaa-aa20d5e4d3fd

The open-access MAF lists 52 somatic variants for this specimen: 44 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 5, Intron 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A4GNT | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 25/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375267880; called by muse, mutect2
- AKR7L | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 88/646 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1399307457; called by muse, mutect2, varscan2
- AL592490.1 | c.1802A>G p.E601G | Missense Mutation (SNP) | VAF 20/560 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV69426152; called by muse, mutect2
- AZGP1 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 106/395 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as rs201532690; called by muse, mutect2, varscan2
- CD22 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 44/544 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768555478; called by muse, mutect2
- CHPF | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 114/732 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs377609172; called by muse, mutect2, varscan2
- CNTNAP3B | c.2503G>T p.G835W | Missense Mutation (SNP) | VAF 426/928 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262260495; called by mutect2, varscan2
- F2 | c.1750C>G p.Q584E | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as CM960525; called by muse, mutect2, varscan2
- KRTAP4-9 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.683); catalogued as rs760671118, COSV66949962; called by muse, mutect2
- MXRA5 | c.3251A>G p.E1084G | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99476693; called by muse, mutect2
- NEDD4 | c.2630C>A p.A877D (on ENST00000508342 / NM_001284338.1; = p.A458D on NM_006154.4) | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as rs145647343; called by mutect2, varscan2
- OR4K15 | c.691T>C p.S231P (on ENST00000305051; = p.S207P on NM_001005486.1) | Missense Mutation (SNP) | VAF 124/617 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59303833; called by muse, mutect2, varscan2
- STX4 | c.232+5_232+8del p.X78_splice | Splice Site (DEL) | VAF 190/223 reads (85%) | catalogued as rs759216449; called by pindel, varscan2
- TMCC2 | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 75/695 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs762041861; called by muse, mutect2, varscan2
- TP53 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 322/355 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs750600586, CM123559, COSV52661339, COSV52708439, COSV53502932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR33 | c.2906C>G p.P969R | Missense Mutation (SNP) | VAF 97/740 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV100460623; called by muse, mutect2, varscan2
- WNK2 | c.3130G>A p.V1044M | Missense Mutation (SNP) | VAF 423/473 reads (89%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs765437518; called by muse, mutect2, varscan2
- ADAT3 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 42/644 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2
- C10orf53 | c.12C>G p.N4K | Missense Mutation (SNP) | VAF 58/682 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- CA6 | c.709G>C p.V237L | Missense Mutation (SNP) | VAF 64/1268 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); called by muse, mutect2
- CSMD2 | c.4329T>A p.A1443= | Splice Region (SNP) | VAF 28/1135 reads (2%) | called by muse, mutect2
- DNAH9 | c.2614T>C p.S872P | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- FAM47C | c.935A>G p.K312R | Missense Mutation (SNP) | VAF 20/636 reads (3%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.714); called by muse, mutect2
- FBXO47 | c.455G>C p.C152S | Missense Mutation (SNP) | VAF 85/364 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HCN3 | c.2081T>A p.L694Q | Missense Mutation (SNP) | VAF 92/782 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HECTD4 | c.3123-1G>A p.X1041_splice | Splice Site (SNP) | VAF 64/278 reads (23%) | called by muse, mutect2, varscan2
- HOXD10 | c.742A>G p.K248E | Missense Mutation (SNP) | VAF 54/624 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.596); called by muse, mutect2
- KIF2B | c.1781A>G p.E594G | Missense Mutation (SNP) | VAF 17/598 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.098); called by muse, mutect2
- KNSTRN | c.250A>C p.K84Q | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- LAMC1 | c.1147C>G p.R383G | Missense Mutation (SNP) | VAF 62/1538 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2
- MDN1 | c.14857G>T p.G4953W | Missense Mutation (SNP) | VAF 26/710 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- MGST1 | c.71T>A p.L24H | Missense Mutation (SNP) | VAF 19/702 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2
- MXRA5 | c.2367A>C p.K789N | Missense Mutation (SNP) | VAF 16/477 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- OASL | c.154A>T p.K52* | Nonsense Mutation (SNP) | VAF 123/623 reads (20%) | called by muse, mutect2, varscan2
- PDE11A | c.2082_2094del p.I694Mfs*45 | Frame Shift Del (DEL) | VAF 85/708 reads (12%) | called by mutect2, pindel, varscan2
- PTPN6 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 35/1060 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2
- RIMKLB | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 67/532 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SAMD11 | c.576C>G p.Y192* | Nonsense Mutation (SNP) | VAF 49/1082 reads (5%) | called by muse, mutect2
- SHOX | c.858C>G p.H286Q | Missense Mutation (SNP) | VAF 32/561 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SNX29 | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2
- TMPRSS11B | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 59/573 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- ZNF215 | c.616G>T p.A206S | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.018); called by muse, mutect2
- ZNF766 | c.866A>C p.H289P | Missense Mutation (SNP) | VAF 103/754 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF85 | c.188G>C p.W63S | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ARHGAP36 | c.762G>A p.V254= | Silent (SNP) | VAF 14/494 reads (3%) | called by muse, mutect2
- FAM160A1 | c.2475T>C p.P825= | Silent (SNP) | VAF 83/659 reads (13%) | called by muse, mutect2, varscan2
- OR6K2 | c.93G>A p.L31= | Silent (SNP) | VAF 432/989 reads (44%) | called by muse, mutect2, varscan2
- QTRT1 | c.1047C>T p.N349= | Silent (SNP) | VAF 80/688 reads (12%) | called by muse, mutect2, varscan2
- STAB2 | c.3225G>A p.Q1075= | Silent (SNP) | VAF 80/676 reads (12%) | called by muse, mutect2, varscan2
- ALOX15 | c.420-13_420-10del | Intron (DEL) | VAF 83/194 reads (43%) | called by pindel, varscan2
- GET3 | c.459-10C>G | Intron (SNP) | VAF 121/783 reads (15%) | called by muse, mutect2, varscan2
- SNED1 | c.3590-67C>T | Intron (SNP) | VAF 195/308 reads (63%) | called by muse, mutect2, varscan2
